Somatic mutation profile of tumor specimen C3N-02421-01 (aliquot CPT0146780010) from CPTAC case C3N-02421, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 58.9 years (21,515 days).
Specimen C3N-02421-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55739cc7-e08b-4d29-86c4-15c6c8b07724.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02421-71 (Blood Derived Normal), aliquot CPT0146810002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d5d7b6b-cb18-4b92-9cdb-b1d6542b60dd

The open-access MAF lists 52 somatic variants for this specimen: 32 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 12, Frame Shift Del 7, Intron 5, Nonsense Mutation 2, 3'UTR 1, In Frame Del 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.266C>A p.S89* | Nonsense Mutation (SNP) | VAF 13/345 reads (4%) | catalogued as rs876658846, COSV57336728; ClinVar: pathogenic; called by muse, mutect2
- ADGRE1 | c.1660A>G p.S554G | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.136); catalogued as rs1244636572; called by muse, mutect2, varscan2
- AMFR | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1316980971, COSV51924643; called by muse, mutect2, varscan2
- C10orf88 | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs1182026221; called by muse, mutect2, varscan2
- CEP85 | c.1580G>T p.C527F | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1158175598; called by muse, mutect2, varscan2
- DNAJC18 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as rs1055994274; called by muse, mutect2
- EGFR | c.2237_2255delinsT p.E746_S752delinsV | In Frame Del (DEL) | VAF 68/413 reads (16%) | catalogued as rs727504258, COSV51765862; ClinVar: drug response; called by pindel, varscan2*
- ERICH3 | c.2978G>A p.R993H | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs143453759; called by muse, mutect2, varscan2
- FSCB | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 10/103 reads (10%) | catalogued as COSV61219608; called by muse, mutect2
- GABRG2 | c.1109C>T p.S370F (on ENST00000361925 / NM_001375343.1; = p.S330F on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 164/590 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62718046; called by muse, mutect2, varscan2
- GAS6 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs373825026; called by muse, mutect2
- LAMA5 | c.3495C>A p.F1165L | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV53371514; called by muse, mutect2
- NPHS1 | c.1898C>A p.T633N | Missense Mutation (SNP) | VAF 65/338 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.824); catalogued as COSV62289581; called by muse, mutect2, varscan2
- SNTG1 | c.914del p.P305Rfs*6 | Frame Shift Del (DEL) | VAF 14/91 reads (15%) | catalogued as COSV52447113, COSV52473992; called by mutect2, pindel, varscan2
- TOPAZ1 | c.2356G>A p.V786I | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1190329705; called by muse, mutect2, varscan2
- ATP10A | c.2986A>C p.K996Q | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CEACAM21 | c.457A>T p.S153C | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CEACAM8 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- DDX3X | c.1248_1249del p.K417Sfs*15 (on ENST00000399959; = p.K418Sfs*15 on NM_001356.5) | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- FOXL2 | c.279G>C p.K93N | Missense Mutation (SNP) | VAF 67/320 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- H2AC11 | c.38_50del p.A13Vfs*43 | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | called by mutect2, pindel
- HIVEP2 | c.6796G>A p.A2266T | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRDM1 | c.740_741del p.E247Vfs*23 | Frame Shift Del (DEL) | VAF 32/190 reads (17%) | called by pindel, varscan2
- PTPN6 | c.815del p.G272Afs*16 | Frame Shift Del (DEL) | VAF 53/289 reads (18%) | called by mutect2, pindel, varscan2
- RMC1 | c.662A>G p.Q221R | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- SETX | c.5206A>G p.R1736G | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- STAB1 | c.3107C>T p.P1036L | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNRC18 | c.5350G>C p.A1784P | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2
- TNXB | c.6696del p.I2233Sfs*8 (on ENST00000647633; = p.I1986Sfs*8 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | called by mutect2, pindel
- USH2A | c.1095del p.N366Ifs*4 | Frame Shift Del (DEL) | VAF 56/250 reads (22%) | called by mutect2, pindel, varscan2
- ZBED9 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF330 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT tolerated (0.96); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BRF1 | c.1704G>A p.R568= | Silent (SNP) | VAF 51/232 reads (22%) | called by muse, mutect2, varscan2
- DENND1A | c.2781C>T p.A927= | Silent (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2, varscan2
- DNAH12 | c.4860T>A p.I1620= (on ENST00000351747; = p.I1643= on NM_001366028.2) | Silent (SNP) | VAF 32/192 reads (17%) | called by muse, mutect2, varscan2
- ESPNL | c.375C>T p.H125= | Silent (SNP) | VAF 21/191 reads (11%) | catalogued as rs752786261; called by muse, mutect2, varscan2
- FRYL | c.8094C>T p.T2698= | Silent (SNP) | VAF 27/169 reads (16%) | catalogued as rs777158934; called by muse, mutect2, varscan2
- LRRC37A2 | c.3603C>T p.A1201= | Silent (SNP) | VAF 183/1169 reads (16%) | catalogued as rs375018792; called by mutect2, varscan2
- OR6K2 | c.447T>C p.V149= | Silent (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- OR6K6 | c.279C>T p.V93= (on ENST00000368144; = p.V69= on NM_001005184.1) | Silent (SNP) | VAF 35/261 reads (13%) | called by muse, mutect2, varscan2
- OTX1 | c.537G>A p.P179= | Silent (SNP) | VAF 24/135 reads (18%) | catalogued as rs771227762; called by muse, mutect2, varscan2
- PRKY | c.177G>A p.T59= | Silent (SNP) | VAF 54/142 reads (38%) | catalogued as rs775569662; called by muse, mutect2, varscan2
- RALGDS | c.1699C>T p.L567= | Silent (SNP) | VAF 85/443 reads (19%) | catalogued as rs1173871540; called by muse, mutect2, varscan2
- WDR17 | c.1695T>C p.H565= | Silent (SNP) | VAF 24/157 reads (15%) | catalogued as rs1279911501, COSV99708369; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504192 del CTTC | 5'Flank (DEL) | VAF 24/176 reads (14%) | catalogued as rs1565055679; called by pindel, varscan2
- AP1G2 | c.-12C>T | 5'UTR (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- ATG4B | c.538+169C>T | Intron (SNP) | VAF 41/172 reads (24%) | catalogued as rs779175823; called by muse, mutect2, varscan2
- DDX3X | c.104-11T>A | Intron (SNP) | VAF 20/51 reads (39%) | catalogued as rs980049998, COSV67864083; called by muse, mutect2, varscan2
- NAV3 | c.2024-13000C>A | Intron (SNP) | VAF 20/141 reads (14%) | called by muse, mutect2, varscan2
- PEX14 | c.*32G>A | 3'UTR (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- RPS24 | c.391-37C>T | Intron (SNP) | VAF 39/220 reads (18%) | catalogued as rs754719579; called by muse, mutect2, varscan2
- TSPAN17 | c.756+29C>T | Intron (SNP) | VAF 125/444 reads (28%) | called by muse, mutect2, varscan2
